Somatic mutation profile of tumor specimen TCGA-AB-2861-03B (aliquot TCGA-AB-2861-03B-01W-0728-08) from TCGA case TCGA-AB-2861, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute monocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.5 years (27,940 days).
Specimen TCGA-AB-2861-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7c01a91-ce0d-46da-929a-8719f1a5842e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2861-11B (Solid Tissue Normal), aliquot TCGA-AB-2861-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cd208af-2df7-4408-9ac1-ab927314e8d4

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Frame Shift Ins 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADS | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs746368198, CM085211, COSV54368542; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 11/41 reads (27%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ARHGEF5 | c.2597G>A p.R866Q | Missense Mutation (SNP) | VAF 96/807 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754492219, COSV50220167; called by muse, mutect2, varscan2
- BTBD16 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 90/280 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs202065129; called by muse, varscan2
- DUOXA2 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV50994939; called by muse, mutect2, varscan2
- GPATCH8 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 10/142 reads (7%) | catalogued as COSV59193039; called by muse, mutect2
- HDAC2 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV64039225; called by muse, mutect2, varscan2
- KATNAL2 | c.1302C>A p.H434Q (on ENST00000356157 / NM_001353899.1; = p.H362Q on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/268 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV55309280; called by muse, mutect2, varscan2
- MEPE | c.1367G>A p.G456D | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.094); catalogued as COSV63074644; called by muse, mutect2, varscan2
- PCDHA1 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV100974235; called by muse, mutect2
- VARS1 | c.1536C>T p.F512= | Silent (SNP) | VAF 57/144 reads (40%) | catalogued as rs369896276; called by muse, mutect2, varscan2
